Somatic mutation profile of tumor specimen TCGA-BC-A3KG-01A (aliquot TCGA-BC-A3KG-01A-11D-A20W-10) from TCGA case TCGA-BC-A3KG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 68.6 years (25,061 days).
Specimen TCGA-BC-A3KG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f74e462-b761-4c22-a1f7-54a471b84f03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A3KG-10A (Blood Derived Normal), aliquot TCGA-BC-A3KG-10A-01D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9789cd7d-ca93-45db-8785-73174c6383ad

The open-access MAF lists 178 somatic variants for this specimen: 157 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 127, Missense Mutation 25, Silent 14, Splice Site 4, 3'UTR 3, Intron 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF1 | c.3903del p.H1303Tfs*22 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | catalogued as COSV51611446, COSV99143295; called by mutect2, pindel
- CACNA1H | c.6224del p.G2075Dfs*113 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as COSV52355276; called by mutect2, pindel
- CADPS | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV51901891; called by mutect2, varscan2
- CDC123 | c.440+4_440+7del p.X147_splice | Splice Site (DEL) | VAF 25/65 reads (38%) | catalogued as rs1197786067; called by mutect2, pindel, varscan2
- CPT1A | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs573452454, COSV55760828; called by mutect2, varscan2
- CSMD1 | c.3157G>T p.A1053S (on ENST00000520002; = p.A1052S on NM_033225.6) | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.214); catalogued as COSV59381628; called by mutect2, varscan2
- FAT1 | c.2468del p.L823Yfs*9 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as COSV71675371; called by mutect2, pindel
- FOXE1 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64301014; called by muse, mutect2
- GJB4 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58357074; called by muse, mutect2, varscan2
- HADH | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58850196; called by mutect2, varscan2
- HAND1 | c.249del p.R84Gfs*55 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV99163975; called by mutect2, pindel
- HUWE1 | c.11074del p.I3692Lfs*22 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | catalogued as COSV99473295; called by mutect2, pindel
- ITIH5 | c.2338G>T p.V780L | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV53673606; called by mutect2, varscan2
- KRT84 | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV57772289, COSV57773706; called by mutect2, varscan2
- LRRN3 | c.1311del p.S438Afs*20 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV57822371; called by mutect2, pindel
- MSX1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757868861, COSV66947901; called by mutect2, varscan2
- MYH4 | c.3908C>A p.S1303Y | Missense Mutation (SNP) | VAF 96/116 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55125985; called by mutect2, varscan2
- MYT1 | c.871del p.E291Kfs*21 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | catalogued as COSV60513202; called by mutect2, pindel
- NCF2 | c.1064A>C p.K355T | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62316728; called by mutect2, varscan2
- NELFA | c.289T>G p.S97A (on ENST00000542778; = p.S86A on NM_005663.5) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV61608399; called by mutect2, varscan2
- NLGN4X | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52035884; called by mutect2, varscan2
- NUMA1 | c.3771del p.E1258Sfs*58 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as COSV61184893; called by mutect2, pindel
- OR11G2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV62131806, COSV62133077; called by mutect2, varscan2
- PARP14 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs754558736, COSV71735563; called by mutect2, varscan2
- RAVER2 | c.393A>C p.K131N | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV53810812; called by mutect2, varscan2
- RIC1 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV52615363; called by mutect2, varscan2
- RP1 | c.2674del p.A892Qfs*4 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | catalogued as COSV55124937; called by mutect2, pindel
- RP1L1 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61447681; called by muse, varscan2
- RPS6KA3 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 104/285 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV65389409; called by mutect2, varscan2
- SERPINA4 | c.292del p.R98Afs*48 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV54070124; called by mutect2, pindel
- SFI1 | c.1908del p.Q637Rfs*3 (on ENST00000400288 / NM_001007467.3; = p.Q606Rfs*3 on NM_014775.4) | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as COSV101192318; called by mutect2, pindel
- SIDT1 | c.1286del p.L429Cfs*31 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV53500915; called by mutect2, pindel
- SNX14 | c.1725del p.F575Lfs*53 (on ENST00000314673 / NM_001350535.1; = p.F522Lfs*53 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs1311909367; called by pindel, varscan2
- SPEN | c.2392G>C p.D798H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65367388; called by muse, varscan2
- TMEM215 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61364138; called by mutect2, varscan2
- VWCE | c.1466del p.P489Hfs*11 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs753714493; called by pindel, varscan2
- WDR81 | c.5027del p.P1676Rfs*38 (on ENST00000409644 / NM_001163809.2; = p.P625Rfs*38 on NM_152348.4) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as COSV58479927; called by mutect2, pindel
- ZFHX4 | c.4565del p.P1522Lfs*48 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV104378952; called by mutect2, pindel
- ZFP42 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as COSV58819270; called by muse, mutect2, varscan2
- ZFP64 | c.1568del p.P523Rfs*26 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV99402139; called by mutect2, pindel
- ZNF154 | c.205del p.S69Afs*9 | Frame Shift Del (DEL) | VAF 4/50 reads (8%) | catalogued as COSV101377541; called by mutect2, pindel
- ZNF92 | c.1488del p.F496Lfs*6 (on ENST00000328747 / NM_152626.4; = p.F427Lfs*6 on NM_007139.4) | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as COSV60875395; called by mutect2, pindel
- AC068580.4 | c.268del p.Q90Sfs*43 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by pindel, varscan2
- ADCK5 | c.829del p.D277Tfs*63 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- ADGRB1 | c.4408del p.L1470Wfs*30 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- AKAP11 | c.1086del p.F362Lfs*4 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- ANKK1 | c.148del p.I50Sfs*16 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- APLP2 | c.2210del p.P737Qfs*6 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- CACNA1I | c.2622del p.Y875Tfs*11 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- CASZ1 | c.23del p.G8Afs*22 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- CCN3 | c.182del p.C61Sfs*45 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- CD200 | c.768del p.G257Afs*10 (on ENST00000473539 / NM_001004196.3; = p.G232Afs*10 on NM_005944.7 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- CELSR3 | c.9619del p.V3207Cfs*117 | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | called by mutect2, pindel
- CEP164 | c.2587del p.A863Lfs*22 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CEP41 | c.105del p.S35Rfs*2 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- CGN | c.2338del p.A780Pfs*2 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- CHRM4 | c.898del p.S300Vfs*46 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- CIBAR2 | c.468del p.S157Afs*30 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- COL18A1 | c.4202del p.P1401Lfs*45 (on ENST00000359759 / NM_130444.3; = p.P1166Lfs*45 on NM_030582.4) | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by pindel, varscan2
- DIPK1B | c.69del p.L24Sfs*90 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- DNAJC14 | c.629del p.G210Vfs*46 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ENPP2 | c.1464del p.F488Lfs*2 (on ENST00000075322 / NM_001040092.3; = p.F540Lfs*2 on NM_006209.5) | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- FASN | c.2485del p.L829Sfs*64 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- FGFR1 | c.104del p.G35Efs*68 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- GALR2 | c.702del p.T235Hfs*3 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- GPR37 | c.464del p.G155Vfs*16 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- GRIA2 | c.1036del p.R346Gfs*15 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- GSDMD | c.1180del p.E394Sfs*54 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- HELLS | c.2249-2del p.X750_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- HELZ2 | c.1374del p.L459Cfs*18 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- HGSNAT | c.1799del p.K600Rfs*10 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- HOXB3 | c.240del p.E81Sfs*53 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- HYDIN | c.5657C>G p.T1886S | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by mutect2, varscan2
- IGFLR1 | c.353del p.P118Lfs*54 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- INPP5J | c.2192del p.Q731Rfs*27 (on ENST00000331075 / NM_001284285.2; = p.Q363Rfs*27 on NM_001002837.2) | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- KCNF1 | c.631del p.D211Tfs*45 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- KIAA1522 | c.1517del p.G506Vfs*87 (on ENST00000373480 / NM_001198972.2; = p.G565Vfs*87 on NM_020888.3) | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- KIF20B | c.3742del p.E1248Kfs*13 (on ENST00000371728 / NM_001284259.2; = p.E1208Kfs*13 on NM_016195.4) | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- LRP1 | c.6831del p.I2278Lfs*92 | Frame Shift Del (DEL) | VAF 4/52 reads (8%) | called by mutect2, pindel
- LRP6 | c.987del p.E329Dfs*5 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- LZTS3 | c.203del p.F68Sfs*84 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- MLH3 | c.1631del p.N544Ifs*66 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel
- MMP15 | c.499del p.A167Pfs*63 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- MTPN | c.309del p.A104Pfs*21 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- NDRG4 | c.478del p.T160Lfs*17 (on ENST00000570248 / NM_001378344.1; = p.T192Lfs*17 on NM_020465.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- NEBL | c.984del p.G329Afs*9 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- NPAT | c.3335del p.N1112Ifs*30 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by pindel, varscan2
- NR3C2 | c.1350del p.P451Hfs*23 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- NRAP | c.2810del p.G937Afs*8 (on ENST00000359988 / NM_001322945.2; = p.G902Afs*8 on NM_006175.4) | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- NRIP1 | c.2107del p.I703* | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- NRP1 | c.1791del p.N598Tfs*38 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- NRXN2 | c.4468del p.I1490Sfs*76 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- PABPC1 | c.1322del p.G441Vfs*26 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PABPC5 | c.261del p.K87Nfs*14 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- PARM1 | c.745del p.E249Kfs*2 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- PASK | c.1076del p.G359Afs*8 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- PC | c.2928del p.R977Gfs*19 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- PCDHB4 | c.331del p.M111Cfs*11 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- PGM2 | c.1007+2del p.X336_splice | Splice Site (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- PIAS2 | c.947del p.P316Lfs*7 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- PITPNC1 | c.936del p.A313Pfs*3 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, varscan2
- PIWIL2 | c.1344del p.E449Rfs*24 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- PJA2 | c.247del p.D83Ifs*27 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PNRC2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- POLM | c.523del p.R175Afs*22 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- QRSL1 | c.405del p.F135Lfs*32 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- RAB11FIP3 | c.1484del p.L495Rfs*14 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | called by mutect2, pindel
- RANBP2 | c.4241del p.K1414Rfs*12 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- RECQL4 | c.1711del p.A571Qfs*7 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- RHBDF2 | c.840_842del p.E280del | In Frame Del (DEL) | VAF 24/32 reads (75%) | called by pindel, varscan2
- ROBO4 | c.2833del p.L945* | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- SERPINA6 | c.460del p.E154Rfs*5 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- SERPINB5 | c.744del p.K248Nfs*34 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- SERPINB7 | c.789del p.P264Qfs*4 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- SERPINE2 | c.19del p.L7Sfs*7 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- SH2B2 | c.1497del p.T500Pfs*15 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- SIGLEC9 | c.423del p.L142* | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- SLC1A7 | c.730del p.A244Pfs*15 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- SLC22A2 | c.414+1del p.X138_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SLC25A28 | c.556del p.A186Qfs*3 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- SLC25A46 | c.1247del p.N416Ifs*6 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- SLC38A10 | c.1674del p.K559Rfs*146 (on ENST00000374759 / NM_001037984.3; = p.K559Rfs*? on NM_138570.4) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- SLC45A4 | c.1691del p.G564Afs*25 (on ENST00000517878 / NM_001286646.2; = p.G513Afs*25 on NM_001080431.2) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel
- SLIT1 | c.1837del p.D613Mfs*3 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- SMCHD1 | c.1888del p.R630Dfs*32 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SNU13 | c.140del p.N47Tfs*9 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- SOX30 | c.1891del p.Y631Tfs*36 (on ENST00000265007 / NM_178424.2; = p.T467Qfs*19 on NM_007017.2) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SPAG5 | c.745del p.S249Pfs*22 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- SPATA31A1 | c.1643del p.L548* | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | called by mutect2, pindel
- SPIRE2 | c.1339del p.A447Pfs*70 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- SRRM2 | c.4428del p.R1477Efs*71 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- TBC1D9B | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TET1 | c.6164del p.N2055Ifs*9 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel
- TMEM209 | c.249del p.W83* | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- TNKS | c.2873del p.P958Qfs*14 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- TRHDE | c.732del p.E244Dfs*89 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- TRRAP | c.3862del p.D1288Ifs*21 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- TTYH2 | c.769del p.W257Gfs*26 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- VAT1L | c.149del p.F50Sfs*31 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- VPS11 | c.322del p.S108Pfs*3 (on ENST00000620429; = p.S652Pfs*3 on NM_021729.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- VSIG10 | c.89del p.A30Vfs*21 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- VWA8 | c.1749del p.E583Dfs*18 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- WDFY3 | c.1972del p.L658Sfs*8 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- ZBTB9 | c.928del p.T310Pfs*15 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ZFAND4 | c.1377del p.N460Tfs*5 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- ZFHX4 | c.1789del p.T597Lfs*36 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ZNF214 | c.1789del p.L597Ffs*17 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- ZNF236 | c.513del p.H171Qfs*2 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- ZNF3 | c.1110del p.C370* | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- ZNF329 | c.419del p.N140Ifs*3 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ZNF33B | c.1893del p.H631Qfs*2 | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | called by mutect2, pindel
- ZNF444 | c.198del p.E66Dfs*4 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- ZNF473 | c.2230del p.E744Sfs*58 | Frame Shift Del (DEL) | VAF 5/58 reads (9%) | called by mutect2, pindel
- ZNF518A | c.544del p.C182Vfs*10 | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- ZNF578 | c.1209del p.E403Dfs*73 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ZNF83 | c.693del p.K231Nfs*22 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- ZNF93 | c.708del p.A237Pfs*148 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- CAPN12 | c.1512G>C p.P504= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV53150676; called by muse, mutect2, varscan2
- DNAJC5G | c.162G>A p.R54= | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as COSV56081221; called by mutect2, varscan2
- EPOR | c.609C>A p.T203= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as COSV55801530; called by muse, mutect2, varscan2
- NDST2 | c.1281T>C p.A427= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1408046517, COSV55217842; called by muse, varscan2
- OR4C12 | c.291T>A p.A97= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as COSV58861079; called by mutect2, varscan2
- PRKAG2 | c.648A>G p.P216= | Silent (SNP) | VAF 53/65 reads (82%) | catalogued as rs751742816, COSV55241122; called by muse, mutect2, varscan2
- RASSF10 | c.819G>T p.V273= | Silent (SNP) | VAF 128/294 reads (44%) | catalogued as COSV61754683; called by mutect2, varscan2
- SCN1A | c.4410G>A p.G1470= (on ENST00000303395 / NM_001202435.3; = p.G1459= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 82/189 reads (43%) | catalogued as COSV57687028; called by mutect2, varscan2
- SEMA3E | c.1245A>C p.I415= | Silent (SNP) | VAF 132/156 reads (85%) | catalogued as COSV57108306; called by mutect2, varscan2
- TBC1D9B | c.171C>T p.A57= | Silent (SNP) | VAF 56/115 reads (49%) | called by mutect2, varscan2
- TCEANC | c.945T>A p.L315= (on ENST00000380600 / NM_001297563.2; = p.L345= on NM_152634.4) | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV59040994; called by mutect2, varscan2
- TTR | c.117T>A p.A39= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as COSV52702071; called by mutect2, varscan2
- VWA5A | c.2115T>C p.G705= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV64414496; called by muse, mutect2, varscan2
- XYLT1 | c.2505C>A p.T835= | Silent (SNP) | VAF 89/183 reads (49%) | catalogued as COSV54493328; called by mutect2, varscan2
- ACE | c.1921+339del | Intron (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ASTE1 | c.*2del | 3'UTR (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- C14orf178 | n.578del | RNA (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- HERC2P3 | n.790del | RNA (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- RAD23B | c.*2018A>G | 3'UTR (SNP) | VAF 25/54 reads (46%) | catalogued as rs765338010; called by muse, mutect2, varscan2
- TAC3 | c.292+127G>C | Intron (SNP) | VAF 46/123 reads (37%) | called by mutect2, varscan2
- ZNF572 | c.*5del | 3'UTR (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel
